Somatic mutation profile of tumor specimen MP2PRT-PATINB-TMP1-A (aliquot MP2PRT-PATINB-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATINB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,515 days).
Specimen MP2PRT-PATINB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 066c2863-ab23-4fa5-8400-33119627d3fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATINB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATINB-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/417ee14f-26c8-46a4-8f46-adbe810dc831

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 93/409 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGAP6 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 35/485 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375940153, COSV57298186, COSV57299143; called by muse, mutect2
- FLT3 | c.1730A>C p.Q577P | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54056525; called by muse, mutect2
- GRIN2A | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV58031046; called by muse, mutect2, varscan2
- KRT76 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs771208701, COSV60120536; called by muse, varscan2
- UBR1 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51928421; called by muse, mutect2, varscan2
- USH2A | c.1061G>T p.W354L | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100231643; called by muse, mutect2
- DMD | c.3844C>A p.L1282I | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- IQCH | c.2290A>G p.N764D | Missense Mutation (SNP) | VAF 149/420 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RTL1 | c.3289G>A p.V1097M | Missense Mutation (SNP) | VAF 188/929 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- SATL1 | c.1112C>T p.A371V (on ENST00000395409; = p.A558V on NM_001012980.2) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- TEX15 | c.1558G>A p.E520K (on ENST00000256246; = p.E903K on NM_001350162.2) | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- WNK1 | c.6885G>T p.M2295I (on ENST00000315939 / NM_018979.4; = p.M2047I on NM_014823.3) | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2
- MSI1 | c.324G>A p.T108= | Silent (SNP) | VAF 92/298 reads (31%) | catalogued as rs1047873772, COSV57456289; called by muse, mutect2, varscan2
- SMLR1 | c.210C>T p.I70= | Silent (SNP) | VAF 42/361 reads (12%) | catalogued as rs943311101; called by muse, mutect2
- VEZF1 | c.1224G>A p.S408= | Silent (SNP) | VAF 26/386 reads (7%) | catalogued as rs781487035; called by muse, mutect2
- WASF3 | c.1110G>A p.P370= | Silent (SNP) | VAF 48/724 reads (7%) | catalogued as rs940944383, COSV58969531; called by muse, mutect2
